Somatic mutation profile of tumor specimen TCGA-VQ-A8PU-01A (aliquot TCGA-VQ-A8PU-01A-12D-A410-08) from TCGA case TCGA-VQ-A8PU, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 72.9 years (26,625 days).
Specimen TCGA-VQ-A8PU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71e0eeff-3562-4849-b6f9-cc751aab1aa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PU-10B (Blood Derived Normal), aliquot TCGA-VQ-A8PU-10B-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05bb5a98-e1d5-4b13-b340-c552c8c8db08

The open-access MAF lists 140 somatic variants for this specimen: 97 protein-altering or splice-affecting, 41 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 41, Frame Shift Del 4, Nonsense Mutation 3, In Frame Del 3, RNA 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs199660234, COSV55458205; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC008397.2 | c.1568T>G p.L523R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as rs764071894, COSV99441009; called by muse, mutect2, varscan2
- ADAT3 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.691); catalogued as rs1482019898, COSV100280127; called by muse, mutect2, varscan2
- ADPRM | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.6); catalogued as COSV100541326; called by muse, mutect2, varscan2
- AIP | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99653456; called by muse, mutect2, varscan2
- ASPM | c.9416A>G p.K3139R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as COSV99659265; called by muse, mutect2, varscan2
- ATRNL1 | c.3638G>T p.W1213L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100368916; called by muse, mutect2, varscan2
- AVL9 | c.1572C>A p.D524E | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.34); catalogued as COSV100594463; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3037T>G p.S1013A | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100863558; called by muse, mutect2, varscan2
- C9orf116 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100876603; called by muse, varscan2
- C9orf116 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100876596; called by muse, varscan2
- CA10 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs1281393846, COSV99561024; called by muse, mutect2, varscan2
- CEP112 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs373914387; called by muse, mutect2, varscan2
- CILP2 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs375522239; called by muse, mutect2, varscan2
- CLSTN2 | c.1932G>C p.W644C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV101515393; called by muse, mutect2, varscan2
- COL4A4 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV100305932; called by muse, mutect2, varscan2
- CPSF2 | c.1826G>A p.R609K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.04); catalogued as COSV100102406; called by muse, mutect2, varscan2
- CYP39A1 | c.1250+1G>C p.X417_splice | Splice Site (SNP) | VAF 24/44 reads (55%) | catalogued as COSV99241721; called by muse, mutect2, varscan2
- DBR1 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1371477896, COSV99604335; called by muse, mutect2, varscan2
- DEAF1 | c.525G>C p.Q175H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV100101641; called by muse, mutect2
- DHX16 | c.1668C>A p.D556E | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.402); catalogued as COSV100905106; called by muse, mutect2, varscan2
- ECHS1 | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100881875; called by muse, mutect2, varscan2
- ECT2L | c.1982C>G p.T661S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as rs776457446, COSV100871718; called by mutect2, varscan2
- EPG5 | c.5281A>G p.M1761V | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99956236; called by muse, mutect2, varscan2
- ERGIC1 | c.632T>A p.V211E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.248); catalogued as COSV101194785; called by muse, mutect2, varscan2
- F2 | c.1709G>C p.G570A | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100319268, COSV56368690; called by muse, mutect2, varscan2
- FAM13A | c.2298G>T p.K766N | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as rs764237667, COSV52003529, COSV99982667; called by muse, mutect2, varscan2
- FRMD3 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772773617, COSV100418077; called by muse, mutect2, varscan2
- GABRA4 | c.428A>T p.H143L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV51922116, COSV99973281; called by muse, mutect2
- GOLPH3L | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99653556; called by muse, mutect2, varscan2
- GPR32 | c.993G>C p.L331F | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99567041; called by muse, mutect2, varscan2
- GSX2 | c.707C>G p.A236G | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100482456; called by muse, mutect2, varscan2
- HK1 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 79/115 reads (69%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.785); catalogued as rs548019222, COSV53864886; called by muse, mutect2, varscan2
- IFT140 | c.751A>T p.N251Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV101276282; called by muse, mutect2, varscan2
- KASH5 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV101483373; called by muse, mutect2, varscan2
- KAT8 | c.418C>G p.R140G | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54896227, COSV99571049; called by muse, mutect2, varscan2
- KCNA3 | c.968T>G p.F323C | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100871184; called by muse, mutect2, varscan2
- KIAA1549L | c.4501C>T p.R1501C (on ENST00000321505; = p.R1798C on NM_012194.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58580895; called by muse, mutect2, varscan2
- KPRP | c.602G>A p.C201Y | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100908644; called by muse, mutect2, varscan2
- LAMB2 | c.4864C>T p.Q1622* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV100025706; called by muse, mutect2, varscan2
- LIPI | c.1310C>T p.T437I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as COSV100753293; called by muse, mutect2, varscan2
- LRRC17 | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 62/83 reads (75%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1337447951, COSV50864431; called by muse, mutect2, varscan2
- MCC | c.1776C>A p.S592R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100201889; called by muse, mutect2, varscan2
- MICAL1 | c.2998C>A p.L1000M | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99237671; called by muse, mutect2, varscan2
- MIEF2 | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.758); catalogued as COSV100493393, COSV100493444; called by muse, mutect2
- MYPN | c.3624C>A p.D1208E | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.999); catalogued as rs754106892, COSV100589404; called by muse, mutect2, varscan2
- NAIF1 | c.278G>C p.G93A | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV100895692; called by muse, mutect2, varscan2
- NBEAL2 | c.7582G>T p.V2528L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV99434014; called by muse, mutect2, varscan2
- NFKBIB | c.812T>C p.M271T | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.977); catalogued as rs764322441, COSV100548271; called by muse, mutect2, varscan2
- NPTX1 | c.1170G>C p.E390D | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.994); catalogued as COSV100150814; called by muse, mutect2, varscan2
- NUP107 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs201038520, COSV57495770; called by muse, mutect2, varscan2
- OR13F1 | c.102G>T p.M34I | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV100594658; called by muse, mutect2, varscan2
- PCDHA9 | c.1204A>C p.K402Q | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as COSV100968900; called by muse, mutect2, varscan2
- PEAK1 | c.4219G>C p.D1407H | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100432261; called by muse, mutect2, varscan2
- PEG3 | c.1430A>G p.E477G | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99686689; called by muse, mutect2, varscan2
- PEG3 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99686690; called by muse, mutect2, varscan2
- PLEKHM1 | c.1938A>C p.E646D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101378642; called by muse, mutect2, varscan2
- PRKACG | c.135A>C p.E45D | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV99597723; called by muse, mutect2, varscan2
- PRX | c.1537C>G p.P513A | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99397328; called by muse, mutect2, varscan2
- PSD2 | c.1125G>C p.M375I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99216932; called by muse, mutect2, varscan2
- PTK2B | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1307626029, COSV99531811; called by muse, mutect2
- RERE | c.3928C>T p.R1310* | Nonsense Mutation (SNP) | VAF 12/12 reads (100%) | catalogued as rs638843, COSV61952917; called by muse, mutect2, varscan2
- RNF169 | c.1456G>A p.G486S | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55132722; called by muse, mutect2, varscan2
- SASS6 | c.1689G>C p.L563F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.462); catalogued as COSV99790479; called by muse, mutect2, varscan2
- SCAI | c.328C>G p.Q110E (on ENST00000336505 / NM_001144877.3; = p.Q133E on NM_173690.5) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.894); catalogued as COSV100332082; called by muse, mutect2, varscan2
- SERPINE1 | c.395T>A p.F132Y | Missense Mutation (SNP) | VAF 164/192 reads (85%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.513); catalogued as COSV99776506; called by muse, mutect2, varscan2
- SLC6A7 | c.1666G>T p.V556L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV100045874; called by muse, mutect2, varscan2
- SMAD4 | c.1521A>T p.K507N | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV100747412, COSV61688004, COSV61695133; called by muse, mutect2, varscan2
- SMURF2 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV99300208; called by muse, mutect2, varscan2
- SPRED2 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs749448972, COSV100710023; called by muse, mutect2, varscan2
- SPTBN2 | c.1903G>C p.A635P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV100017939, COSV100019618, COSV59454169; called by muse, mutect2, varscan2
- SREBF2 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100761318; called by muse, varscan2
- SRP68 | c.53G>C p.G18A | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as COSV100203385; called by muse, mutect2, varscan2
- SUPV3L1 | c.278T>G p.V93G | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV100669447; called by muse, mutect2, varscan2
- TOP2B | c.1042G>A p.D348N (on ENST00000264331 / NM_001330700.2; = p.D343N on NM_001068.3) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as COSV99978964; called by muse, mutect2, varscan2
- TRPC6 | c.215T>G p.L72R | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as COSV100723355; called by muse, mutect2, varscan2
- UBE2O | c.1217G>A p.C406Y | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1409414263, COSV100083970; called by muse, mutect2, varscan2
- UBR2 | c.498T>A p.H166Q | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100868374; called by muse, mutect2, varscan2
- UBR2 | c.2661C>G p.S887R | Missense Mutation (SNP) | VAF 151/237 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0.269); catalogued as COSV100867317; called by muse, mutect2, varscan2
- UBXN6 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100010685; called by muse, mutect2, varscan2
- WDR72 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as rs925563718, COSV100854088; called by muse, mutect2, varscan2
- ZIM3 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs756657875, COSV99517503; called by muse, mutect2, varscan2
- ZNF467 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs763097613, COSV100117712; called by muse, varscan2
- ZNF536 | c.1001C>G p.P334R | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV100834506; called by muse, mutect2, varscan2
- ZNF83 | c.749A>C p.Q250P | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.636); catalogued as COSV99991114; called by muse, mutect2, varscan2
- ZNFX1 | c.1409C>G p.S470C | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1262757584, COSV100870697; called by muse, mutect2
- ZNFX1 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 80/422 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100870700; called by muse, mutect2, varscan2
- AFF2 | c.3402_3404+11del p.X1134_splice | Splice Site (DEL) | VAF 29/41 reads (71%) | called by mutect2, pindel
- COL5A1 | c.2064_2081del p.P692_G697del | In Frame Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel
- MYH1 | c.3636_3648del p.D1212Efs*2 | Frame Shift Del (DEL) | VAF 31/51 reads (61%) | called by mutect2, pindel, varscan2
- NRAP | c.35_46del p.G12_P15del | In Frame Del (DEL) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- PDPR | c.1632_1639del p.L545Pfs*5 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- PRAMEF2 | c.1207_1219del p.G403* | Frame Shift Del (DEL) | VAF 43/74 reads (58%) | called by mutect2, pindel, varscan2
- PTPN6 | c.184_226del p.D62Wfs*25 | Frame Shift Del (DEL) | VAF 12/96 reads (13%) | called by mutect2, pindel
- TFDP2 | c.606dup p.E203Rfs*57 (on ENST00000489671 / NM_001178139.2; = p.E143Rfs*57 on NM_006286.5) | Frame Shift Ins (INS) | VAF 42/92 reads (46%) | called by mutect2, varscan2
- TRIP10 | c.1626_1643del p.G543_I548del (on ENST00000313244 / NM_001288962.2; = p.G487_I492del on NM_004240.4) | In Frame Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel
- ABHD16A | c.54G>C p.R18= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV101012168; called by muse, mutect2, varscan2
- ARID2 | c.4644C>A p.G1548= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100535197, COSV57594571; called by muse, mutect2, varscan2
- ATPAF2 | c.360C>G p.T120= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as rs1483427443, COSV101466922; called by muse, mutect2, varscan2
- ATXN1 | c.816C>G p.P272= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV99784550; called by muse, mutect2, varscan2
- COL4A4 | c.639T>A p.P213= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV100305930; called by muse, mutect2, varscan2
- CPSF6 | c.1434T>C p.H478= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1165738551, COSV99878883; called by muse, varscan2
- CXCR1 | c.720C>A p.A240= | Silent (SNP) | VAF 38/53 reads (72%) | catalogued as COSV99826196; called by muse, mutect2, varscan2
- CYP1B1 | c.1614C>G p.A538= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99307125; called by muse, mutect2, varscan2
- DEF8 | c.42G>A p.A14= | Silent (SNP) | VAF 41/78 reads (53%) | catalogued as rs1318074496, COSV51917755; called by muse, mutect2, varscan2
- DHRS2 | c.621C>T p.D207= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs778936300, COSV99158660; called by muse, mutect2, varscan2
- DLX6 | c.660T>C p.S220= | Silent (SNP) | VAF 59/70 reads (84%) | catalogued as COSV99142184; called by muse, mutect2, varscan2
- DYNLRB2 | c.21C>T p.T7= | Silent (SNP) | VAF 29/41 reads (71%) | catalogued as COSV100009603; called by muse, mutect2, varscan2
- FAM71F1 | c.462C>A p.L154= | Silent (SNP) | VAF 55/213 reads (26%) | catalogued as COSV100170806; called by muse, mutect2, varscan2
- FLRT2 | c.726G>C p.L242= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV58142216, COSV58151200; called by muse, mutect2, varscan2
- GNA14 | c.420T>C p.C140= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100502412; called by muse, mutect2, varscan2
- HHIPL2 | c.1332C>T p.D444= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs767728663, COSV58567187; called by muse, mutect2, varscan2
- IFT80 | c.264A>G p.K88= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100424236; called by muse, mutect2, varscan2
- LARGE2 | c.1308C>G p.A436= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99137994; called by muse, varscan2
- LIMCH1 | c.2172G>A p.T724= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs759422245, COSV58282866, COSV58288484; called by muse, mutect2, varscan2
- MAST4 | c.933G>A p.E311= (on ENST00000403625 / NM_001164664.2; = p.E122= on NM_015183.3) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99842371; called by muse, mutect2, varscan2
- MUC16 | c.25813T>C p.L8605= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- MYH4 | c.1650C>A p.S550= | Silent (SNP) | VAF 33/52 reads (63%) | catalogued as COSV99700124; called by muse, mutect2, varscan2
- NCOA5 | c.348C>A p.S116= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99275075; called by muse, mutect2, varscan2
- NKX3-1 | c.639G>T p.V213= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs1353665023, COSV101082694; called by muse, mutect2, varscan2
- OR51Q1 | c.543C>T p.C181= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV100332772; called by muse, mutect2, varscan2
- PADI3 | c.441C>T p.G147= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs745514948, COSV100968374, COSV64934424; called by muse, mutect2, varscan2
- PCDHB7 | c.1620G>A p.A540= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV50754071; called by muse, mutect2, varscan2
- PCDHGA12 | c.171G>A p.R57= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV99337164; called by muse, mutect2
- POLR3C | c.37C>T p.L13= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100492727; called by muse, mutect2
- PPP1R18 | c.696G>A p.K232= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs915455775, COSV99223499; called by muse, mutect2, varscan2
- PREX1 | c.2691C>T p.F897= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as rs763619070, COSV64247734; called by muse, mutect2, varscan2
- PSKH1 | c.666G>A p.E222= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99344382; called by muse, mutect2, varscan2
- QTRT1 | c.711G>C p.S237= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs760339670, COSV99138983; called by muse, mutect2, varscan2
- RUSC1 | c.504C>A p.S168= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV52740859, COSV99429343; called by muse, mutect2, varscan2
- SEC16A | c.3348T>G p.P1116= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV99255637; called by muse, mutect2, varscan2
- SH3BP4 | c.696C>G p.V232= | Silent (SNP) | VAF 43/61 reads (70%) | catalogued as COSV100748955; called by muse, mutect2, varscan2
- SLC7A9 | c.987C>T p.Y329= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs369810846; called by muse, mutect2, varscan2
- SPATS1 | c.48C>G p.L16= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs139954152, COSV99913013; called by muse, mutect2, varscan2
- SV2A | c.537C>T p.D179= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs781860737, COSV64966188; called by muse, mutect2, varscan2
- SYNJ2 | c.2911C>T p.L971= | Silent (SNP) | VAF 45/56 reads (80%) | catalogued as COSV100839975; called by muse, mutect2, varscan2
- WDR33 | c.1734T>A p.S578= | Silent (SNP) | VAF 56/78 reads (72%) | catalogued as COSV100459425; called by muse, mutect2, varscan2
- ISCA1P1 | n.16G>C | RNA (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2
- OR2W5 | n.1256C>T | RNA (SNP) | VAF 15/43 reads (35%) | catalogued as rs139575695; called by muse, mutect2, varscan2
